Somatic mutation profile of tumor specimen TCGA-YL-A9WH-01A (aliquot TCGA-YL-A9WH-01A-11D-A377-08) from TCGA case TCGA-YL-A9WH, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.8 years (24,755 days).
Specimen TCGA-YL-A9WH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 692e61eb-ec1f-40f7-aebf-b9ba18708776.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A9WH-10A (Blood Derived Normal), aliquot TCGA-YL-A9WH-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4459163a-0d45-4d2f-b75c-010af91f03fa

The open-access MAF lists 61 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 40, Silent 13, Splice Site 3, Splice Region 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF6 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434229, CM034818, COSV100883988, COSV65419171; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 27/37 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as COSV101330204; called by muse, mutect2, varscan2
- AMOT | c.2641A>G p.I881V (on ENST00000371959 / NM_001113490.1; = p.I472V on NM_133265.3) | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100495650; called by muse, mutect2
- BRIP1 | c.3474G>T p.L1158F | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.05); catalogued as COSV99371265; called by muse, mutect2, varscan2
- CD5L | c.677A>C p.N226T | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV100941226; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2633C>T p.T878M | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs112982005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNOT4 | c.327C>A p.N109K | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1563040199, COSV100212350; called by muse, mutect2, varscan2
- CWF19L1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs199591943, COSV100821652; called by muse, mutect2, varscan2
- CYP2C19 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 104/194 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV100990645; called by muse, mutect2, varscan2
- DDX23 | c.1967T>C p.L656P | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV99975156; called by muse, mutect2, varscan2
- DEF8 | c.1104+1G>A p.X368_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | catalogued as rs1053825653, COSV51920731; called by muse, mutect2
- FAT3 | c.11591G>A p.R3864H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372126226; called by muse, mutect2, varscan2
- FGA | c.1297C>A p.L433M | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs1388705104, COSV57399214; called by muse, mutect2, varscan2
- GPR139 | c.169A>G p.R57G | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316083998, COSV100430070; called by muse, mutect2, varscan2
- GRIN2A | c.927G>C p.K309N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV100411307; called by muse, mutect2, varscan2
- GRK4 | c.980G>A p.R327Q (on ENST00000398052 / NM_182982.3; = p.R295Q on NM_005307.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs540093348, COSV100584329; called by muse, mutect2, varscan2
- HSPA8 | c.1091A>G p.N364S | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as COSV99914670; called by muse, mutect2
- IL3RA | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs141828957, COSV100452420; called by muse, mutect2, varscan2
- JAK3 | c.1358T>A p.L453H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV101513041; called by muse, mutect2
- KMT2C | c.13319A>G p.Y4440C | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV51471900; called by muse, mutect2, varscan2
- LSM11 | c.659T>G p.L220R | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99644125; called by muse, mutect2, varscan2
- MAP2 | c.2770A>G p.R924G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV99562035; called by muse, mutect2, varscan2
- MXI1 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs752984163, COSV99491575; called by muse, mutect2, varscan2
- MXRA5 | c.8478C>G p.H2826Q | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); catalogued as COSV54244227, COSV99479723; called by muse, varscan2
- MYBBP1A | c.554T>A p.L185H | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771031263, COSV99627255; called by muse, mutect2, varscan2
- NALCN | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV51920711, COSV51970651; called by muse, mutect2, varscan2
- NPAP1 | c.3296G>T p.C1099F | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV99051835; called by muse, mutect2, varscan2
- PKD1L1 | c.3511G>T p.V1171L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs539595370, COSV99221678; called by muse, mutect2, varscan2
- PPP1R3A | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as COSV52889108, COSV99494653; called by muse, mutect2, varscan2
- PPP4R3B | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99702837; called by muse, mutect2, varscan2
- PROKR1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58138665; called by muse, mutect2, varscan2
- RNF186 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100909129; called by muse, mutect2
- RTP1 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV100398803; called by muse, mutect2, varscan2
- SAG | c.600C>G p.F200L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV101300717; called by muse, mutect2, varscan2
- SHE | c.1025-1G>C p.X342_splice | Splice Site (SNP) | VAF 24/47 reads (51%) | catalogued as rs1223644620, COSV100496249; called by muse, mutect2, varscan2
- SNX25 | c.869A>G p.D290G | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.455); catalogued as rs1275408500, COSV99253612; called by muse, mutect2, varscan2
- SOX6 | c.981G>A p.K327= | Splice Region (SNP) | VAF 28/75 reads (37%) | catalogued as COSV100323491; called by muse, mutect2, varscan2
- STAU2 | c.553C>T p.P185S (on ENST00000524300 / NM_001164380.2; = p.P153S on NM_014393.2) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV100869136, COSV100869328; called by mutect2, varscan2
- SYNDIG1 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770624311, COSV65232499; called by muse, mutect2, varscan2
- TMEM140 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs151072952; called by muse, mutect2
- TNPO3 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1373878463, COSV99603673; called by muse, mutect2, varscan2
- TRIM33 | c.1695G>A p.Q565= | Splice Region (SNP) | VAF 45/135 reads (33%) | catalogued as rs1557857563, COSV100635839; called by muse, mutect2, varscan2
- WDR13 | c.428A>T p.E143V | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV99489667; called by muse, mutect2, varscan2
- ZNF160 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV100762513; called by muse, mutect2, varscan2
- ZNF76 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs974250747, COSV99988014; called by muse, mutect2, varscan2
- ZNRF3 | c.427-2A>G p.X143_splice (on ENST00000544604 / NM_001206998.2; = p.X43_splice on NM_032173.3) | Splice Site (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100239118, COSV60437104; called by muse, mutect2, varscan2
- CNTNAP5 | c.2390del p.T797Kfs*33 | Frame Shift Del (DEL) | VAF 45/112 reads (40%) | called by mutect2, pindel, varscan2
- ACTL9 | c.1023C>T p.C341= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1249003885, COSV61005046; called by muse, mutect2, varscan2
- ASXL1 | c.1830C>T p.G610= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as rs199829982; called by muse, mutect2, varscan2
- BICD1 | c.1933C>A p.R645= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as COSV99863127; called by muse, mutect2, varscan2
- CADPS2 | c.2097G>C p.L699= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100466561; called by muse, mutect2, varscan2
- DBX1 | c.726C>T p.R242= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV57054462; called by muse, mutect2, varscan2
- DNA2 | c.1638A>G p.L546= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as COSV100622885; called by muse, mutect2, varscan2
- ISL2 | c.697C>A p.R233= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs997553390, COSV99320921; called by muse, mutect2, varscan2
- LONRF2 | c.2151C>T p.L717= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs116101039; called by muse, varscan2
- MYO19 | c.2550G>A p.S850= (on ENST00000614623 / NM_001163735.1; = p.S650= on NM_025109.5) | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs768916037; called by muse, mutect2, varscan2
- OR3A1 | c.258T>C p.S86= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs760477994, COSV100041863; called by muse, mutect2, varscan2
- PCDH11Y | c.360C>T p.G120= (on ENST00000400457 / NM_032973.2; = p.G109= on NM_032971.3) | Silent (SNP) | VAF 49/88 reads (56%) | catalogued as COSV99293051; called by muse, mutect2, varscan2
- PRDM16 | c.2061C>T p.G687= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs1480706485, COSV99575889; called by muse, mutect2, varscan2
- S100A7L2 | c.291C>T p.S97= | Silent (SNP) | VAF 48/151 reads (32%) | catalogued as rs568882807, COSV64194750; called by muse, mutect2, varscan2
